Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4801, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4801-01A (Primary Tumor).

[page 1 of 2]
TCGA - BP - 4801

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with history of renal mass, spontaneous pneumothorax.

Specimens Submitted:

1: RENAL MASS, HILAR, LEFT; PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. RENAL MASS, HILAR, LEFT; PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.2 cm.

Local Invasion (for renal pelvic tumors):

Not Identified

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not Identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section and is labeled "left renal hilar tumor, stitch marks deepest surgical margin for FS. ". It consists of a 4 x 4 x 0.5 cm portion of kidney with a suture marking the deep margin. The margin is inked green and the specimen is serially sectioned to reveal a 3.2 x 2.8 x 2.1 cm tumor with a variegated brown-tan and yellow, solid and cystic cut surface. The clearance from the resection margin is 0.3 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

TM - tumor with margin

TF - tumor with perinephric fat

RS - representative sections

Summary of Sections:

Part 1: RENAL MASS, HILAR, LEFT; PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	fsc	1
2	rs	2
1	tf	1
3	tm	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: STITCH MARGIN NEGATIVE. RENAL CORTICAL NEOPLASM. CLEAR CELL TYPE SUSPECT ON REPRESENTATIVE SECTION. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file b968c077-aa7a-4e6b-b79c-91198b156aba (TCGA-BP-4801.C4BFDCCF-E1AC-4BCA-BBD6-5E6C20FA40FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).